Somatic mutation profile of tumor specimen TARGET-30-PAUIWS-01A (aliquot TARGET-30-PAUIWS-01A-01D) from TARGET case TARGET-30-PAUIWS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.5 years (925 days).
Specimen TARGET-30-PAUIWS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5edf69b4-6c40-4447-b717-77fd557e08f1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUIWS-10A (Blood Derived Normal), aliquot TARGET-30-PAUIWS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a95b7c68-f95a-4cc8-9950-e09ad90af955

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCRN3 | c.160-1G>T p.X54_splice | Splice Site (SNP) | VAF 15/115 reads (13%) | catalogued as rs1553508155; called by muse, varscan2
- USP34 | c.8176C>T p.Q2726* | Nonsense Mutation (SNP) | VAF 46/226 reads (20%) | catalogued as COSV68402022; called by muse, mutect2, varscan2
